Somatic mutation profile of tumor specimen TCGA-ZJ-A8QO-01A (aliquot TCGA-ZJ-A8QO-01A-11D-A37N-09) from TCGA case TCGA-ZJ-A8QO, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; Age at diagnosis: 73.2 years (26,723 days).
Specimen TCGA-ZJ-A8QO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4cf7966-eec8-4a50-b59d-cf8bd3ce42c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-A8QO-10A (Blood Derived Normal), aliquot TCGA-ZJ-A8QO-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f2531d2-4046-4f8b-8c3e-e7937f256749

The open-access MAF lists 73 somatic variants for this specimen: 55 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 17, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 2, In Frame Del 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADVL | c.1606-1G>A p.X536_splice | Splice Site (SNP) | VAF 5/41 reads (12%) | catalogued as rs1057517386, COSV99138416; ClinVar: likely pathogenic; called by muse, mutect2
- ADRB3 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100799821; called by muse, mutect2, varscan2
- ANO6 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.022); catalogued as COSV100262803; called by muse, mutect2, varscan2
- ARHGAP9 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs762525918, COSV100712372; called by muse, mutect2, varscan2
- ASB9 | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100995420; called by muse, mutect2, varscan2
- CDC123 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV99826816; called by muse, mutect2, varscan2
- CDH7 | c.2113G>T p.V705F | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as COSV100541896; called by muse, mutect2, varscan2
- CEACAM4 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs557074639, COSV99700991; called by muse, mutect2, varscan2
- CFP | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901392; called by muse, mutect2, varscan2
- CHERP | c.738C>A p.C246* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV52222118; called by muse, mutect2
- CPT1C | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV54918786, COSV54920289, COSV99773338; called by muse, mutect2, varscan2
- CREBBP | c.3710G>A p.C1237Y | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52115539, COSV99270266; called by muse, mutect2, varscan2
- DNAH10 | c.11711G>A p.R3904Q (on ENST00000409039; = p.R3843Q on NM_207437.3) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.396); catalogued as rs148915943, COSV68997830; called by muse, mutect2, varscan2
- DNAH11 | c.4307G>A p.R1436Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs766184035, COSV60949226; called by muse, mutect2, varscan2
- DYNC1I1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV61466983; called by muse, mutect2, varscan2
- ELMOD3 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs771811463, COSV100226175; called by muse, mutect2, varscan2
- EPHA2 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100626040, COSV64453977; called by muse, mutect2, varscan2
- EXTL3 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754024716, COSV99593872; called by muse, mutect2, varscan2
- FER1L6 | c.4361C>T p.A1454V | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV101205681; called by muse, mutect2, varscan2
- FIP1L1 | c.330T>C p.Y110= | Splice Region (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100184332; called by muse, mutect2, varscan2
- FLT3 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV99608142; called by muse, mutect2
- FSIP2 | c.19273G>A p.V6425I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.917); catalogued as rs747508888, COSV100554641; called by muse, mutect2, varscan2
- GEMIN8 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100256978; called by muse, mutect2
- GLT8D1 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 9/15 reads (60%) | catalogued as rs1388959236, COSV56478305; called by muse, mutect2, varscan2
- IQSEC2 | c.2572G>A p.E858K (on ENST00000642864 / NM_001111125.3; = p.E653K on NM_015075.2) | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1376121300, COSV64726826; called by muse, mutect2, varscan2
- IRS4 | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100929497; called by muse, mutect2, varscan2
- ITGA10 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782416335, COSV100994813; called by muse, mutect2, varscan2
- KIAA1109 | c.3321G>A p.K1107= | Splice Region (SNP) | VAF 21/98 reads (21%) | catalogued as COSV99145872, COSV99151199; called by muse, mutect2, varscan2
- KRT80 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs774237997, COSV100502569; called by muse, mutect2, varscan2
- LNPEP | c.2903C>T p.A968V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as COSV99183504; called by muse, mutect2, varscan2
- LRRK2 | c.5603T>G p.I1868S | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV100109703; called by muse, mutect2, varscan2
- MDH1B | c.1442dup p.N481Kfs*20 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | catalogued as rs1298797334; called by mutect2, varscan2
- OR4X1 | c.304del p.L102Sfs*12 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as COSV60722898; called by mutect2, pindel, varscan2
- PCDHB4 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs375620247; called by muse, mutect2, varscan2
- POLG | c.2193C>A p.S731R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.054); catalogued as COSV99174632; called by muse, mutect2
- PTPRF | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as rs1242703150, COSV100740779; called by muse, mutect2, varscan2
- SCRN3 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777659517, COSV99767180; called by muse, mutect2, varscan2
- SCRT1 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100146394; called by muse, mutect2, varscan2
- SMC4 | c.1824del p.K608Nfs*15 | Frame Shift Del (DEL) | VAF 41/104 reads (39%) | catalogued as rs1038263749; called by mutect2, varscan2
- SPTA1 | c.5432G>A p.R1811Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748672916, COSV63752118; called by muse, mutect2, varscan2
- SRRM4 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99938193; called by muse, mutect2, varscan2
- STARD8 | c.2455T>C p.Y819H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.261); catalogued as COSV99366569; called by muse, mutect2, varscan2
- SYCP2L | c.1181C>T p.S394L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV51652902; called by muse, mutect2, varscan2
- SYNE2 | c.15956A>T p.N5319I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV100647250, COSV59950675; called by muse, mutect2, varscan2
- SYT10 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as COSV99951162; called by muse, mutect2, varscan2
- TET3 | c.2423C>G p.T808R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99996254; called by muse, mutect2, varscan2
- THBS4 | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1439370230, COSV100644234; called by muse, mutect2
- TMEM201 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV100440347; called by muse, mutect2, varscan2
- TRPM6 | c.2608G>A p.V870M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs180963446, COSV62513995; called by muse, mutect2, varscan2
- TRPM8 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs140382067; called by muse, mutect2
- VWA2 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV100073470; called by muse, mutect2, varscan2
- ZNF611 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs750624146, COSV100160162, COSV60543804; called by muse, mutect2, varscan2
- NFKBIA | c.297dup p.D100Rfs*29 | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- SH3RF1 | c.1938_1985del p.I647_A662del | In Frame Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel
- WDR35 | c.3036del p.L1013Cfs*37 (on ENST00000345530 / NM_001006657.2; = p.L1002Cfs*37 on NM_020779.4) | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- ANK2 | c.7968G>A p.E2656= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100000738, COSV52163643; called by muse, mutect2, varscan2
- ASTN1 | c.715C>T p.L239= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99921008, COSV99923302; called by muse, mutect2, varscan2
- CLUH | c.3816C>T p.N1272= (on ENST00000435359; = p.N1311= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101425685; called by muse, mutect2, varscan2
- DSC3 | c.1494C>T p.P498= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs774337244, COSV100844563, COSV64574567; called by muse, mutect2, varscan2
- ERO1B | c.147C>T p.I49= | Silent (SNP) | VAF 45/158 reads (28%) | catalogued as rs754348396, COSV100523989; called by muse, mutect2, varscan2
- ESR1 | c.951T>C p.S317= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99238543; called by muse, mutect2, varscan2
- ETF1 | c.99C>T p.S33= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100860091; called by muse, mutect2, varscan2
- MFSD11 | c.1078C>T p.L360= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs778254396, COSV100333693; called by muse, mutect2, varscan2
- MKI67 | c.4479C>A p.A1493= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV100896375; called by muse, mutect2, varscan2
- MPI | c.651G>A p.V217= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs762051658, COSV60397257; called by muse, mutect2, varscan2
- SCN3A | c.1434A>G p.L478= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs146202943; called by muse, mutect2, varscan2
- SLC18A2 | c.924C>T p.I308= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1467229966, COSV53692567; called by muse, mutect2, varscan2
- STYXL2 | c.960C>T p.S320= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs1031089851, COSV99608886; called by muse, mutect2, varscan2
- TSC2 | c.2154C>T p.R718= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs878854081, COSV99553459; called by muse, mutect2, varscan2
- WDR81 | c.4053G>A p.K1351= (on ENST00000409644 / NM_001163809.2; = p.K300= on NM_152348.4) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100488717; called by muse, mutect2, varscan2
- ZNF543 | c.1626G>A p.K542= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100386720; called by muse, mutect2, varscan2
- ZNF786 | c.1692G>A p.P564= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs777617948, COSV60277286; called by muse, mutect2, varscan2
- SALL2 | c.*571A>G | 3'UTR (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100444251; called by muse, mutect2, varscan2
